Somatic mutation profile of tumor specimen TCGA-BA-A6DG-01A (aliquot TCGA-BA-A6DG-01A-21D-A30E-08) from TCGA case TCGA-BA-A6DG, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; Tumor grade: G2; Age at diagnosis: 49.4 years (18,052 days).
Specimen TCGA-BA-A6DG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67236aa1-4a00-41ed-a198-9736caeed20f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-A6DG-10A (Blood Derived Normal), aliquot TCGA-BA-A6DG-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f1b2cef-8931-4554-bcd4-67eea5faf20f

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Nonsense Mutation 2, Intron 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.838A>G p.R280G | Missense Mutation (SNP) | VAF 7/52 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs753660142, COSV52662754, COSV52708728, COSV52851287; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ALG6 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.263); catalogued as rs1301268508, COSV99672889; called by muse, mutect2
- AMY2B | c.1231A>C p.N411H | Missense Mutation (SNP) | VAF 30/474 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV100796137; called by muse, mutect2
- CDC42 | c.238G>T p.V80F | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV100212472; called by muse, mutect2, varscan2
- DNAH5 | c.1384T>C p.F462L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.33); catalogued as COSV99442934; called by muse, mutect2, varscan2
- DTWD1 | c.567G>T p.L189F | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV99233462; called by muse, mutect2, varscan2
- GRM8 | c.1909T>A p.F637I | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV58807913; called by muse, mutect2
- MPP7 | c.1079A>G p.Y360C | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs770100022, COSV100516678; called by muse, mutect2
- NANOS2 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV58025573, COSV58025723; called by muse, varscan2
- NFXL1 | c.2428C>T p.Q810* | Nonsense Mutation (SNP) | VAF 5/90 reads (6%) | catalogued as COSV67432135; called by muse, mutect2
- TASOR2 | c.2480A>G p.N827S | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100049795; called by muse, mutect2
- TF | c.263A>C p.D88A | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.485); catalogued as COSV99395190; called by muse, mutect2
- RASA1 | c.898_899+15del p.X300_splice | Splice Site (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- AVPR1A | c.666C>T p.G222= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as rs974264460, COSV54546313, COSV54548251; called by muse, mutect2
- CAVIN1 | c.514C>T p.L172= | Silent (SNP) | VAF 24/233 reads (10%) | catalogued as COSV100824484; called by muse, mutect2, varscan2
- GPR39 | c.1110C>T p.H370= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs1210975128, COSV100256672; called by muse, mutect2, varscan2
- OR1J4 | c.51C>T p.L17= | Silent (SNP) | VAF 13/145 reads (9%) | catalogued as COSV100534210; called by muse, mutect2
- USP34 | c.10338T>C p.D3446= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as rs746837716, COSV100815902; called by muse, mutect2, varscan2
- PCDHGA1 | c.2421+17A>C | Intron (SNP) | VAF 6/59 reads (10%) | catalogued as COSV100965915; called by muse, mutect2
- PNPLA7 | c.31-242G>A | Intron (SNP) | VAF 11/143 reads (8%) | catalogued as rs201390415, COSV99479774; called by muse, mutect2
